Gene-level copy-number profile of tumor specimen TCGA-61-2111-01A from TCGA case TCGA-61-2111, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 61.6 years (22,517 days).
Specimen TCGA-61-2111-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.18d87466-bae2-4006-bed7-2657e9f070d3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2111-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/4bc098d6-cd85-450a-9029-8f26eccebb7f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 106; copy number 1: 19,736; copy number 2: 31,958; copy number 3: 6,872; copy number 4: 837; copy number 5: 213; copy number 6: 34; copy number 7: 55.

Homozygous deletions (total copy number 0; autosomes only): 106 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:46,761,894–50,801,309, 106 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 302 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,708,931–41,383,590, 98 genes, copy number 5–7 (broad region; genes not listed).
- chr1:56,823,679–56,996,757, 4 genes, copy number 6: AL360295.1, C8A, C8B, AL161740.1.
- chr5:7,396,138–8,080,761, 9 genes, copy number 5 (within-gene range 3–5): ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC116361.1, AC091941.1.
- chr5:28,285,964–30,693,984, 26 genes, copy number 5–7 (within-gene range 3–7): LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, AC099517.1.
- chr8:63,651,457–64,369,176, 4 genes, copy number 5 (within-gene range 2–5): AC018953.2, LINC01414, AC069133.1, LINC01289.
- chr8:69,175,579–70,424,576, 23 genes, copy number 5: AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2.
- chr12:24,810,024–24,949,101, 1 gene, copy number 6 (within-gene range 2–6): BCAT1.
- chr12:24,902,309–27,972,733, 79 genes, copy number 5–6 (broad region; genes not listed).
- chr19:28,418,483–29,841,818, 34 genes, copy number 5 (within-gene range 4–5): AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2.
- chr19:52,949,379–53,356,906, 24 genes, copy number 5: ZNF816, AC010328.3, ZNF702P, AC010328.2, AC010328.1, ERVV-1, ERVV-2, ZNF160, ZNF415, ZNF347, ZNF665, AC092070.1, AC092070.2, NDUFV2P1, ZNF677, AC092070.3, VN1R2, VN1R4, AC092070.4, FAM90A27P, BIRC8, FAM90A28P, VN1R6P, ZNF845.

Autosomal genes at a single copy (total copy number 1): 17,315. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
